Surgical pathology report (de-identified scan), TCGA case TCGA-OE-A75W, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Saint Mary's Health Care, specimen TCGA-OE-A75W-01A (Primary Tumor).

[page 1 of 2]
1st Addendum Report

* Final Report *

* Final Report *

1ST ADDENDUM REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

ICD O-3

Adenocarcinoma, duct NOS
8500/3

Site: Pancreas tail
C25.2

Op 8/19/13

ADDENDUM REPORT

A, B: PANCREAS CANCER PROFILE

SPECIMEN TYPE: DISTAL PANCREATECTOMY WITH SPLENECTOMY.

CLINICAL/WORKING STAGE: N/A

TISSUE COLD ISCHEMIA TIME:

TISSUE DURATION IN 10 PERCENT NEUTRAL BUFFERED FORMALIN: 27.25
HOURS.

TUMOR SITE: PANCREAS TAIL.

TUMOR SIZE: 4.5 x 2.6 x 2.7 CM.

HISTOLOGIC TYPE AND GRADE: DUCTAL ADENOCARCINOMA,
WELL-DIFFERENTIATED (GRADE I).

Note: The tumor displays a cystic component, evidence of possible
origin
within a mucinous cystadenocarcinoma.

EXTENT OF INVASION: THE TUMOR SHOWS LIMITED, FOCAL EXTENSION INTO
PERIPANCREATIC FAT.

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 2]
1st Addendum Report

* Final Report *

LYMPH-VASCULAR INVASION: NOT IDENTIFIED.

PERINEURAL INVASION: NOT IDENTIFIED.

MARGINS: MARGINS FREE OF TUMOR.

TUMOR MEASURES 1.5 CM FROM THE PROXIMAL SURGICAL PANCREATIC MARGIN.

TUMOR MEASURES LESS THAN 1 MILLIMETER FROM THE POSTERIOR
(RETROPERITONEAL)
MARGIN.

REGIONAL LYMPH NODES: TWO PERIPANCREATIC LYMPH NODES ARE NEGATIVE
FOR TUMOR.

THE ADDITIONAL FAT-CLEARED LYMPH NODE DISSECTION SHOWS 20 OF 20
LYMPH NODES NEGATIVE FOR METASTATIC TUMOR.

FAT-CLEARED LYMPH NODE SUMMARY: ZONE 1, 12; 2, 3; 3, 1; 4, 4.

ADDITIONAL PATHOLOGIC FINDINGS:

BENIGN SPLEEN. UNINVOLVED PANCREAS SHOWS NO SIGNIFICANT
PATHOLOGIC CHANGE. THE MESENTERIC NODULE (PART B) CONSISTS OF
ADIPOSE STROMA WITH FAT NECROSIS.
DISTANT METASTASIS: NOT APPLICABLE.

CANCER STAGE: pT3, pN0

Note: This addendum is issued to report the results of the
fat-cleared lymph
node dissection.

(Electronic Signature)

Printed by:
Printed on:

Page 2 of 3
(Continued)

Criteria	lu 7/29/13	No

Source: NCI Genomic Data Commons file e365cc44-108b-49f9-b5a6-69884b3fbfae (TCGA-OE-A75W.D0E49643-BAB9-42A7-86AE-46BE5EF4BD0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).